Somatic mutation profile of tumor specimen TARGET-10-PATDRC-03A (aliquot TARGET-10-PATDRC-03A-01D) from TARGET case TARGET-10-PATDRC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,463 days).
Specimen TARGET-10-PATDRC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 132b64ac-eb61-48fb-a325-6fe5d7915550.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDRC-10A (Blood Derived Normal), aliquot TARGET-10-PATDRC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c6b7819-38c8-4eb1-8211-a28aaa94908f

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Silent 4, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INSC | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762539775, COSV65409267; called by muse, mutect2, varscan2
- KCNA7 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750280618, COSV55502938; called by muse, varscan2
- NEK7 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66314409, COSV66314834; called by muse, mutect2, varscan2
- OR4K13 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs199734457; called by muse, mutect2, varscan2
- PLCD3 | c.2300T>A p.L767Q | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51958666; called by muse, mutect2, varscan2
- SETD2 | c.517_518insC p.L173Sfs*64 | Frame Shift Ins (INS) | VAF 41/113 reads (36%) | catalogued as COSV57432354; called by mutect2, pindel, varscan2
- ZSWIM8 | c.3077C>A p.S1026Y (on ENST00000605216 / NM_001242487.2; = p.S1031Y on NM_015037.3) | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67131468; called by muse, mutect2, varscan2
- ANKDD1B | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.938); called by muse, mutect2
- BPIFB1 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, varscan2
- CLEC4D | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GLS | c.957C>A p.N319K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HRC | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MIB2 | c.2161C>A p.H721N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- PGAM2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.094); called by muse, mutect2
- RBAK | c.1753C>A p.H585N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCEANC | c.891C>A p.C297* (on ENST00000380600 / NM_001297563.2; = p.C327* on NM_152634.4) | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- ZNF276 | c.1470C>A p.H490Q (on ENST00000443381 / NM_001113525.2; = p.H415Q on NM_152287.4) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF618 | c.1076C>A p.A359E (on ENST00000374126 / NM_001318042.2; = p.A327E on NM_001318040.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF662 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- HCN1 | c.90G>A p.A30= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1290982240; called by muse, mutect2, varscan2
- PTPRN2 | c.1596C>T p.D532= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs374889194, COSV67027840; called by muse, mutect2
- SAC3D1 | c.753C>A p.G251= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- ZZEF1 | c.3573T>G p.T1191= | Silent (SNP) | VAF 42/130 reads (32%) | called by muse, varscan2
